Gene-level copy-number profile of tumor specimen ALCH-B2FS-TTP1-A from ALCHEMIST case ALCH-B2FS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 77.0 years (28,141 days).
Specimen ALCH-B2FS-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 950b728c-389d-4643-a6fc-cc07c364cb4e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2FS-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,802 have no estimate.
https://portal.gdc.cancer.gov/files/0ef396e0-84f3-4810-a96f-90b0d20dd680

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 375; copy number 1: 22,798; copy number 2: 32,514; copy number 3: 2,982; copy number 4: 86; copy number 5: 5; copy number 6: 3; copy number 8: 1; copy number 10: 21; copy number 18: 7; copy number 26: 18; copy number 28: 9; copy number 46: 2.

Homozygous deletions (total copy number 0; autosomes only): 140 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:923,928–959,309, 2 genes: SAMD11, NOC2L.
- chr2:131,527,675–131,536,988, 2 genes: CCDC74A, MED15P4.
- chr2:241,808,312–241,817,413, 2 genes: AC131097.2, NEU4.
- chr5:180,967,189–180,970,762, 2 genes: AC091874.2, AC091874.1.
- chr5:181,301,967–181,342,213, 4 genes: RNU6-705P, AC138035.1, AC138035.3, AC138035.2.
- chr7:4,775,615–4,794,397, 3 genes: AP5Z1, MIR4656, AC092610.1.
- chr7:4,811,188–4,811,289, 1 gene (within-gene range 0–1): Y_RNA.
- chr7:5,274,369–5,513,809, 10 genes: SLC29A4, TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589.
- chr7:56,809,214–56,848,800, 1 gene: AC118758.2.
- chr9:39,886,861–39,892,895, 3 genes: RN7SL763P, SNORA70, CR769767.1.
- chr9:39,983,821–39,984,401, 1 gene: RPL7AP49.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr9:129,081,111–129,090,438, 1 gene: DOLPP1.
- chr9:129,097,854–129,100,266, 1 gene (within-gene range 0–1): AL158151.2.
- chr9:129,869,605–129,869,671, 1 gene (within-gene range 0–1): MIR6855.
- chr9:133,061,978–133,087,355, 2 genes: CEL, CELP.
- chr9:133,250,401–133,318,469, 3 genes: ABO, Y_RNA, LCN1P2.
- chr11:494,512–507,300, 1 gene: RNH1.
- chr11:64,035,970–64,103,653, 2 genes (within-gene range 0–2): AP000721.2, AP006333.2.
- chr13:113,748,511–113,751,089, 1 gene: LINC00552.
- chr14:100,537,147–100,587,413, 2 genes (within-gene range 0–1): BEGAIN, AL845552.2.
- chr15:19,987,656–20,096,029, 10 genes: IGHV3OR15-7, IGHD5OR15-5A, IGHD4OR15-4A, IGHD3OR15-3A, IGHD2OR15-2A, IGHD1OR15-1A, FAM30B, AC127381.1, BCAR1P1, RN7SL584P.
- chr15:23,430,839–23,435,212, 1 gene: HERC2P6.
- chr15:25,169,337–25,250,940, 45 genes (within-gene range 0–1): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:5,010,909–5,066,110, 3 genes (within-gene range 0–1): NAGPA-AS1, NAGPA, C16orf89.
- chr16:88,079,161–88,087,383, 1 gene (within-gene range 0–1): AC134312.4.
- chr16:88,382,959–88,537,031, 4 genes: ZNF469, ZFPM1, MIR5189, AC116552.1.
- chr17:22,266,395–22,332,410, 4 genes: AC138761.1, AC138761.2, FAM27E5, AC087575.1.
- chr17:80,960,766–81,183,166, 17 genes (within-gene range 0–2): AC127496.4, AC127496.1, RPL12P37, CHMP6, AC127496.6, AC127496.7, AC127496.5, AC127496.2, BAIAP2-DT, BAIAP2, AATK, MIR657, MIR3065, MIR338, MIR1250, AC115099.1, PVALEF.
- chr17:81,197,393–81,200,288, 1 gene (within-gene range 0–1): AC027601.2.
- chr19:18,899,514–18,919,387, 1 gene (within-gene range 0–2): COPE.
- chr21:44,300,051–44,340,470, 5 genes: PFKL, AP001062.3, CFAP410, AP001062.1, AP001062.2.
- chr22:50,185,913–50,199,598, 2 genes (within-gene range 0–1): TRABD, AL022328.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 66 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene, copy number 5 (within-gene range 2–5): RSRP1.
- chr1:25,272,393–25,330,445, 2 genes, copy number 5: RHD, SDHDP6.
- chr6:33,410,399–33,418,317, 2 genes, copy number 5: PHF1, CUTA.
- chr9:64,878,790–64,889,063, 2 genes, copy number 6: AC125634.1, RNU6-1293P.
- chr11:68,460,731–68,615,334, 1 gene, copy number 28 (within-gene range 2–28): PPP6R3.
- chr11:68,612,899–70,436,584, 54 genes, copy number 10–46: AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr17:45,263,119–45,327,497, 2 genes, copy number 26 (within-gene range 1–26): MAP3K14, RNA5SP443.
- chr22:21,341,595–21,358,067, 2 genes, copy number 6–8: PPP1R26P5, LINC01651.

Autosomal genes at a single copy (total copy number 1): 20,273. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
